Somatic mutation profile of tumor specimen C3L-02888-02 (aliquot CPT0166540033) from CPTAC case C3L-02888, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 62.8 years (22,949 days).
Specimen C3L-02888-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e71a5f9-09bf-4086-8786-47ee81839a6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02888-31 (Blood Derived Normal), aliquot CPT0166580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7106833-ea1d-4f9c-83d5-e298ad62f791

The open-access MAF lists 85 somatic variants for this specimen: 60 protein-altering or splice-affecting, 17 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 17, Nonsense Mutation 5, Splice Site 2, RNA 2, Intron 2, 3'Flank 1, Splice Region 1, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 143/620 reads (23%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.16501C>T p.R5501* | Nonsense Mutation (SNP) | VAF 24/141 reads (17%) | catalogued as rs886041398, CM105482, COSV56407191; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 81/428 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 47/171 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 104/614 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs377381847; called by muse, mutect2, varscan2
- ACTN3 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 34/215 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs761392416; called by muse, mutect2, varscan2
- ADAM12 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs576203316, COSV64113235; called by muse, mutect2
- ADCY4 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 98/497 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs138257439; called by muse, mutect2, varscan2
- AJAP1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100981455; called by muse, mutect2, varscan2
- BHLHE22 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 149/1049 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.591); catalogued as rs747740432; called by muse, mutect2, varscan2
- CAMLG | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 107/592 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.149); catalogued as COSV99777812; called by muse, mutect2, varscan2
- CCDC88B | c.3926G>A p.R1309Q | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749137059, COSV57267343; called by muse, mutect2, varscan2
- CHRM3 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV55083588; called by muse, mutect2, varscan2
- COL6A5 | c.2579A>G p.D860G | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs536077168; called by muse, mutect2
- CPXCR1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV52160939; called by muse, mutect2
- DCT | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs750417204; called by muse, mutect2, varscan2
- EPHX2 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 64/490 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs574326427, COSV66845380; called by muse, mutect2, varscan2
- GDI1 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 131/650 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV50130963; called by muse, mutect2, varscan2
- GUCY2D | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as CM155804, COSV54699605; called by muse, mutect2
- IRF6 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 57/220 reads (26%) | catalogued as CD022553, CM067420, CM090291; called by muse, mutect2, varscan2
- KIAA1210 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs369057021, COSV68175642; called by muse, mutect2
- LMBRD1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 166/679 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV65298480; called by muse, mutect2, varscan2
- MAGEH1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs917411358; called by muse, mutect2, varscan2
- MIB2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs1250293210, COSV61755226; called by muse, mutect2, varscan2
- MMP9 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 91/531 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777794038; called by muse, mutect2, varscan2
- MUC16 | c.6353C>T p.A2118V | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs777515183, COSV67476661; called by muse, mutect2, varscan2
- NEURL1B | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 79/330 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.255); catalogued as rs939595606, COSV104425029; called by muse, mutect2, varscan2
- NLRC5 | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs758740455, COSV52659890, COSV99067521; called by muse, mutect2, varscan2
- PINK1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 103/708 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs61735932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITPNM2 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.718); catalogued as rs551002395, COSV54895410; called by muse, mutect2, varscan2
- PLSCR2 | c.223C>T p.P75S (on ENST00000497985 / NM_001199978.1; = p.P2S on NM_020359.2) | Missense Mutation (SNP) | VAF 126/641 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1410433569; called by muse, mutect2, varscan2
- PRAMEF20 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 223/1381 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs962195338; called by muse, mutect2, varscan2
- RASGRF1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.097); catalogued as rs778369712, COSV69177099; called by muse, mutect2
- RNF150 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 124/651 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99058792; called by muse, mutect2, varscan2
- RYR1 | c.5047G>A p.A1683T | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1455863679, COSV62098288; called by muse, mutect2, varscan2
- SH3BP5 | c.563A>C p.N188T | Missense Mutation (SNP) | VAF 62/466 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV99508018; called by muse, mutect2, varscan2
- SLC8A2 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 119/510 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs1447849965; called by muse, mutect2, varscan2
- SMC1A | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 170/933 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.376); catalogued as COSV100447708; called by muse, mutect2, varscan2
- SMS | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 65/548 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs746297985, COSV65113563; called by muse, mutect2, varscan2
- TEX35 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as COSV51103268; called by muse, mutect2, varscan2
- UTP14A | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 72/399 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs749551821; called by muse, mutect2, varscan2
- ZNF264 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 60/446 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs918246748; called by muse, mutect2, varscan2
- ANK1 | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 137/849 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASPH | c.415+1G>A p.X139_splice | Splice Site (SNP) | VAF 37/311 reads (12%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.260A>T p.N87I | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, varscan2
- CSNK2A1 | c.220A>C p.K74Q | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); called by muse, varscan2
- EBAG9 | c.352T>G p.F118V | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FABP9 | c.242T>G p.V81G | Missense Mutation (SNP) | VAF 72/263 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- FYB1 | c.1818C>T p.S606= | Splice Region (SNP) | VAF 34/256 reads (13%) | called by muse, mutect2, varscan2
- KAT6A | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 180/547 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LYST | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MALRD1 | c.5105T>A p.L1702H | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.404); called by muse, mutect2
- MICALL2 | c.2576A>G p.D859G | Missense Mutation (SNP) | VAF 61/253 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MISP3 | c.602C>G p.A201G (on ENST00000269720; = p.A59G on NM_001291291.2) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NCOR2 | c.4937-1G>A p.X1646_splice | Splice Site (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- OSCAR | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 118/631 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PAFAH2 | c.1144A>G p.T382A | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAB5C | c.52A>G p.K18E | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- SDC3 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 45/289 reads (16%) | called by muse, mutect2
- SEPTIN7 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ARG2 | c.828C>T p.G276= | Silent (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- CHST2 | c.531G>A p.S177= | Silent (SNP) | VAF 69/273 reads (25%) | catalogued as rs368136453; called by muse, mutect2, varscan2
- DPYSL3 | c.156C>T p.F52= | Silent (SNP) | VAF 85/458 reads (19%) | catalogued as COSV100574882, COSV58330595; called by muse, mutect2, varscan2
- F2RL2 | c.57T>C p.C19= | Silent (SNP) | VAF 51/307 reads (17%) | called by muse, mutect2, varscan2
- ITGAX | c.2493C>T p.Y831= | Silent (SNP) | VAF 62/227 reads (27%) | catalogued as rs146985733; called by muse, mutect2, varscan2
- LRFN1 | c.1821G>A p.A607= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- LRSAM1 | c.1299G>T p.S433= | Silent (SNP) | VAF 59/278 reads (21%) | catalogued as rs755070977; called by muse, mutect2, varscan2
- MAGEL2 | c.3549C>T p.L1183= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as COSV58565766; called by muse, mutect2, varscan2
- NKAPL | c.417G>A p.P139= | Silent (SNP) | VAF 32/203 reads (16%) | catalogued as COSV59197910; called by muse, mutect2, varscan2
- PARP14 | c.5157C>T p.A1719= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2
- PCDHA7 | c.429G>A p.A143= | Silent (SNP) | VAF 72/367 reads (20%) | called by muse, mutect2, varscan2
- PCDHA9 | c.429G>A p.A143= | Silent (SNP) | VAF 81/974 reads (8%) | catalogued as rs1554142578, COSV65323171; called by muse, mutect2
- RUNX3 | c.435G>A p.G145= | Silent (SNP) | VAF 50/236 reads (21%) | called by muse, mutect2, varscan2
- SPTBN5 | c.9903G>A p.A3301= | Silent (SNP) | VAF 42/271 reads (15%) | catalogued as rs771946309; called by muse, mutect2, varscan2
- TBC1D22B | c.504G>A p.S168= | Silent (SNP) | VAF 37/293 reads (13%) | catalogued as rs767807891; called by muse, mutect2, varscan2
- TEX13C | c.594C>T p.A198= | Silent (SNP) | VAF 82/521 reads (16%) | called by muse, mutect2, varscan2
- THOC2 | c.2574G>A p.A858= | Silent (SNP) | VAF 86/507 reads (17%) | catalogued as rs763790733; called by muse, mutect2, varscan2
- AC235097.1 | n.504G>A | RNA (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- CEP57 | c.1273-50del | Intron (DEL) | VAF 25/179 reads (14%) | catalogued as rs760000276; called by mutect2, pindel, varscan2
- GPC6 | c.-45C>T | 5'UTR (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- HIF3A | c.877+119C>T | Intron (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- IMPDH1 | chr7:128409773 G>T | 5'Flank (SNP) | VAF 108/727 reads (15%) | catalogued as rs1192233344; called by muse, mutect2, varscan2
- RNU6-817P | chr1:116410102 C>T | 3'Flank (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- SPAG11B | c.*68C>T | 3'UTR (SNP) | VAF 87/1355 reads (6%) | catalogued as rs1433304287, COSV52499308; called by muse, mutect2
- TRIM53BP | n.380G>T | RNA (SNP) | VAF 4/19 reads (21%) | called by mutect2, varscan2
